Surgical pathology report (de-identified scan), TCGA case TCGA-06-0143, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0143-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

06-0143-DIR

Physician(s):
Phy Loca

CLINICAL HISTORY

man has past history of , and a left temporoparietal GBM diagnosed in . Currently, there is questionable MRI progression.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

Brain, site not specified, excision: Glioblastoma, necrotic, quiescent, and viable.

See Microscopy Description and Comment.

COMMENT

The sections contain portions of cerebrum in which there are areas infiltrated by malignant glioma, areas with necrotic tumor undergoing phagocytosis, neoplasm with degenerative changes, and neoplasm with mitoses and microvascular proliferation. There is associated desmoplasia, and zones of white matter geographic necrosis with prominent and atypical glial reaction.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: Date Reported:

Interpretation

NEGATIVE - No evidence of methylated MGMT promoter is detected.

Results-Comments

Received were paraffin curls labeled

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

Requested by:

[page 2 of 2]
[REDACTED]

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

INTRA-OPERATIVE CONSULTATION

A. Brain, excision, touch prep and smears: Gliosis, stypical glial cells, no solid anaplastic neoplasm (requires review of total specimen for diagnosis).

[REDACTED]

[REDACTED], Senior Staff Pathologist

GROSS DESCRIPTION

A.
Received fresh, several fragments, 3.3 cm. in aggregate. On large fragment is soft, tannish-brown; other large fragment is firm, grayish-white and glistening; smaller fragments are semi firm, reddish-brown. In total, A1-A4.

[REDACTED] Senior Staff Pathologist

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates zones of astrocytic proliferation. In these astrocytic hypercellular zones there is active cycling demonstrated by the MIB-1 antiserum. The proliferating cells do not express the p53 mutant protein. There are extensive collections of phagocytic cells demonstrated with the KP1. The CD3 depicts focally rich vascularity with microvessel proliferation.

ICD-9(s):
239.6 239.6

[REDACTED]

Histo Data

Part A: Brain, excision biopsy

Taken:	Received:	
Stain/cnt	Block	Ordered
H/E x 1	1	
CD34-DA x 1	2	
mGFAP-DA x 1	2	
H/E x 1	2	
KP1-DA x 1	2	
MGMT x 1	2	

Requested by: [REDACTED]

Source: NCI Genomic Data Commons file 5769ec6d-d1a3-4307-9aed-68fb671caea0 (TCGA-06-0143.7774787D-3A55-4C74-87E6-DA6E51A16B9E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).